Gene-level copy-number profile of specimen HCM-BROD-0959-C18-85B from HCMI case HCM-BROD-0959-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVC; Tumor grade: G4; Age at diagnosis: 66.3 years (24,234 days).
Specimen HCM-BROD-0959-C18-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file df3d2023-5a5d-4c3a-85c8-cfbc51bf4c85.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0959-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/f52283dc-d5c8-4e26-91a8-fdd9672687d6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 2,990; copy number 2: 24,568; copy number 3: 11,562; copy number 4: 8,621; copy number 5: 6,539; copy number 6: 2,760; copy number 7: 1,060; copy number 8: 36; copy number 9: 213; copy number 10: 6; copy number 12: 10.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,548,564–49,589,529, 7 genes: AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr15:21,010,494–21,103,138, 9 genes: IGHD5OR15-5B, IGHD4OR15-4B, IGHD3OR15-3B, IGHD2OR15-2B, IGHD1OR15-1B, FAM30C, AC037471.1, BCAR1P2, RN7SL400P.
- chr18:72,536,680–72,638,521, 2 genes: CBLN2, HNRNPA1P11.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,624 genes in 43 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:116,164,284–116,278,821, 2 genes, copy number 5: LINC01779, U3.
- chr1:116,694,112–116,742,609, 3 genes, copy number 5: LINC02868, GAPDHP64, NEFHP1.
- chr1:117,272,182–117,321,336, 1 gene, copy number 5: LINC01525.
- chr2:184,593,577–208,222,625, 391 genes, copy number 5–9 (broad region; genes not listed).
- chr4:49,096–10,054,936, 278 genes, copy number 5 (broad region; genes not listed).
- chr4:10,410,996–12,641,009, 19 genes, copy number 5: AC110768.2, ZNF518B, AC005599.1, AC110768.1, CLNK, AC084048.1, MIR572, RNPS1P1, HS3ST1, RNA5SP156, AC006230.1, AC025539.1, AC005699.1, LINC02360, AC108037.1, LINC02270, RNU6-578P, ECM1P2, AC093809.1.
- chr4:14,111,968–14,453,625, 6 genes, copy number 5: LINC01085, AC073848.1, AC092546.1, AC006296.3, AC006296.2, AC006296.1.
- chr4:18,418,662–20,037,972, 10 genes, copy number 5: AC093898.1, AC093871.1, AC006840.1, LINC02438, RNA5SP157, AC024595.1, AC024230.1, AC110767.1, AC114728.1, AC098862.1.
- chr4:25,648,011–26,435,131, 13 genes, copy number 5: SLC34A2, RPS29P11, AC092436.2, MTND4P9, MTND4LP22, MTND3P5, MTCO3P44, SEL1L3, AC092436.3, SMIM20, AC133961.1, AC097714.1, RBPJ.
- chr4:36,244,116–36,641,939, 5 genes, copy number 5: AC104078.1, DTHD1, AC104078.2, LINC02505, AC125336.1.
- chr4:37,821,361–41,268,455, 81 genes, copy number 5 (broad region; genes not listed).
- chr4:45,995,119–46,124,054, 2 genes, copy number 5: RN7SKP199, GABRG1.
- chr4:48,341,529–49,062,081, 12 genes, copy number 5: SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4.
- chr5:58,198–45,895,970, 679 genes, copy number 5–6 (broad region; genes not listed).
- chr6:55,434,373–74,734,319, 178 genes, copy number 5 (broad region; genes not listed).
- chr6:75,084,326–78,946,440, 38 genes, copy number 5–6 (within-gene range 4–6): COL12A1, COX7A2, TMEM30A, TMEM30A-DT, FILIP1, HMGB1P39, AL445465.1, U3, MIR4463, AL445465.2, UBE2V1P15, RNU1-34P, RPL26P20, H3P27, RNU6-1338P, SENP6, AL356057.1, RNU6-1016P, RN7SKP163, MYO6, RNU6-155P, RNA5SP209, IMPG1, Y_RNA, RNU6-248P, RNU6-261P, LINC02540, RNU6-84P, AL591030.1, AL590426.1, AL355612.1, AL365222.1, HTR1B, RPS6P7, MEI4, AL121718.1, AL450327.1, IRAK1BP1.
- chr7:37,032–11,832,198, 227 genes, copy number 5 (broad region; genes not listed).
- chr7:30,697,985–30,757,602, 2 genes, copy number 5 (within-gene range 4–5): INMT, AC006022.1.
- chr7:56,940,341–152,855,378, 1,869 genes, copy number 5–7 (broad region; genes not listed).
- chr8:37,597,480–145,066,685, 1,656 genes, copy number 5–10 (broad region; genes not listed).
- chr9:28,863,626–31,254,777, 17 genes, copy number 5: MIR876, MIR873, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2.
- chr9:33,218,365–34,311,371, 54 genes, copy number 5: SPINK4, BAG1, CHMP5, NFX1, Y_RNA, AQP7, AL356218.2, AQP3, AL356218.1, NOL6, MIR6851, SUGT1P1, AL139008.2, ANKRD18B, AL139008.1, SNX18P7, CYP4F26P, PRSS3P4, TRBV20OR9-2, ANXA2P2, TRBV21OR9-2, TRBV22OR9-2, TRBV23OR9-2, TRBV24OR9-2, TRBV25OR9-2, PTENP1, PTENP1-AS, TRBV26OR9-2, AL356489.2, AL356489.1, AL356489.4, LINC01251, PRSS3, UBE2R2-AS1, TRBV29OR9-2, UBE2R2, Y_RNA, RNU4ATAC11P, UBAP2, SNORD121B, SNORD121A, OSTCP8, RN7SKP114, AL354989.1, DCAF12, TUBB4BP2, AL354989.2, UBAP1, RPL35AP2, AL353662.2, RNA5SP282, AL353662.1, KIF24, RNU2-50P.
- chr9:67,832,765–69,906,227, 36 genes, copy number 5: ANKRD20A1, RNU6-368P, AL353608.2, CBWD3, AL353608.4, FOXD4L3, AL353608.3, AL353608.1, PGM5, PGM5-AS1, AL161457.2, AL161457.1, TMEM252, TMEM252-DT, LINC01506, AL353616.1, PIP5K1B, FAM122A, AL354794.2, AL354794.1, RNU6-820P, PRKACG, AL358113.1, FXN, AL162730.1, TJP2, BANCR, FAM189A2, APBA1, AL355140.1, AL353693.1, AL162412.1, PTAR1, C9orf135-DT, C9orf135, RN7SL570P.
- chr9:74,371,335–138,253,217, 1,261 genes, copy number 5–7 (broad region; genes not listed).
- chr12:66,767–19,720,801, 564 genes, copy number 5–6 (broad region; genes not listed).
- chr12:20,014,780–20,688,583, 6 genes, copy number 5: LINC02398, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1.
- chr12:21,264,600–29,497,686, 145 genes, copy number 5 (broad region; genes not listed).
- chr12:30,230,779–32,646,050, 69 genes, copy number 5 (broad region; genes not listed).
- chr12:33,374,238–37,576,384, 19 genes, copy number 5: SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1, ZNF970P.
- chr12:40,140,926–49,932,764, 241 genes, copy number 5 (broad region; genes not listed).
- chr12:62,935,701–67,352,039, 101 genes, copy number 7–12 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,328 genes, copy number 5–8 (broad region; genes not listed).
- chr15:75,463,251–84,230,136, 247 genes, copy number 5–8 (broad region; genes not listed).
- chr15:84,389,729–93,569,483, 245 genes, copy number 5–7 (broad region; genes not listed).
- chr16:67,517,862–68,594,424, 70 genes, copy number 6 (broad region; genes not listed).
- chr18:45,034–27,247,188, 492 genes, copy number 5–7 (broad region; genes not listed).
- chr18:28,638,714–29,548,241, 7 genes, copy number 5–7: AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1, AC117569.1.
- chr19:13,206,442–16,324,514, 148 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr20:63,090,806–64,327,972, 73 genes, copy number 5–6 (broad region; genes not listed).
- chr21:7,744,962–8,454,792, 26 genes, copy number 5: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.

Autosomal genes at a single copy (total copy number 1): 646. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
